Gene-level copy-number profile of tumor specimen TCGA-DC-6160-01A from TCGA case TCGA-DC-6160, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 68.4 years (24,990 days).
Specimen TCGA-DC-6160-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.4985f2c1-c48d-49cd-b178-8483c0408431.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-6160-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b935a1a-0a14-4437-94e6-7e3410bb1ffe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 15,237; copy number 2: 41,798; copy number 3: 2,354; copy number 4: 100; copy number 5: 39; copy number 6: 169; copy number 7: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DC-6160-01A-11D-1656-01): tumor purity 0.67, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:73,191,604–73,915,340, 5 genes (within-gene range 0–1): RN7SKP19, LINC01360, LINC02238, RNA5SP50, AL591463.1.
- chr20:14,884,250–15,022,958, 4 genes (within-gene range 0–2): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 307 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:18,529,609–18,588,747, 1 gene, copy number 5 (within-gene range 3–5): UEVLD.
- chr11:18,588,781–18,972,703, 19 genes, copy number 5: SPTY2D1OS, AC112694.1, AC112694.2, SPTY2D1, SRSF3P1, TMEM86A, IGSF22, AC103974.1, PTPN5, AC103974.2, MRGPRX8P, MRGPRX7P, AC023078.2, MRGPRX6P, MRGPRX5P, MRGPRX1, AC023078.1, MRGPRX11P, MRGPRX10P.
- chr20:47,950,797–49,484,297, 37 genes, copy number 6 (within-gene range 3–6): AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1, AL121888.2, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1.
- chr20:52,051,663–54,228,052, 35 genes, copy number 7 (within-gene range 4–7): ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4.
- chr20:55,074,644–58,451,101, 64 genes, copy number 7 (broad region; genes not listed).
- chr20:59,852,667–64,079,988, 151 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
